Somatic mutation profile of tumor specimen MP2PRT-PATZSN-TMP1-A (aliquot MP2PRT-PATZSN-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATZSN, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.0 years (1,477 days).
Specimen MP2PRT-PATZSN-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 196e2941-45de-40b4-8338-30ec7a515831.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATZSN-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATZSN-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0f83fdfe-ad24-4bb6-a27c-05ff58c0f472

The open-access MAF lists 30 somatic variants for this specimen: 24 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 5, Nonsense Mutation 2, Frame Shift Ins 1, Splice Site 1, Intron 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RBM20 | c.1900C>T p.R634W | Missense Mutation (SNP) | VAF 83/487 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs796734066, CM107456; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ANXA10 | c.783+6_783+9del p.X261_splice | Splice Site (DEL) | VAF 16/126 reads (13%) | catalogued as rs758252315; called by pindel, varscan2
- H1-7 | c.470G>A p.R157H | Missense Mutation (SNP) | VAF 60/742 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); catalogued as rs957723539, COSV58601775; called by muse, mutect2
- KDM6B | c.2995C>T p.R999C | Missense Mutation (SNP) | VAF 103/618 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.548); catalogued as rs778055366, COSV54688246; called by muse, varscan2
- MYH7 | c.2606G>A p.R869H | Missense Mutation (SNP) | VAF 60/768 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs202141173, HM971868, COSV62516088; ClinVar: pathogenic / likely pathogenic / conflicting interpretations of pathogenicity; called by muse, mutect2
- MYO1E | c.1066G>A p.A356T | Missense Mutation (SNP) | VAF 80/521 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.114); catalogued as rs748877847; called by muse, mutect2, varscan2
- NEDD4L | c.1885G>A p.E629K (on ENST00000400345 / NM_001144967.3; = p.E609K on NM_015277.6) | Missense Mutation (SNP) | VAF 18/394 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.953); catalogued as COSV56850293, COSV99893625; called by muse, mutect2
- NFATC1 | c.587C>T p.P196L | Missense Mutation (SNP) | VAF 58/849 reads (7%) | SIFT tolerated (0.55); PolyPhen probably damaging (0.943); catalogued as rs769462513; called by muse, mutect2
- PRAMEF14 | c.1270C>T p.R424C | Missense Mutation (SNP) | VAF 103/725 reads (14%) | SIFT tolerated (0.19); PolyPhen benign (0.085); catalogued as rs199937476; called by muse, mutect2, varscan2
- RUNX1T1 | c.727C>T p.R243* (on ENST00000265814 / NM_001198628.1; = p.R216* on NM_004349.4 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 32/356 reads (9%) | catalogued as rs866587267, COSV56164293; called by muse, mutect2
- SCAMP4 | c.676G>A p.G226S | Missense Mutation (SNP) | VAF 44/392 reads (11%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0.045); catalogued as rs572977753; called by muse, mutect2, varscan2
- SLC6A11 | c.629G>A p.R210Q | Missense Mutation (SNP) | VAF 63/396 reads (16%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.867); catalogued as rs762627001; called by muse, mutect2, varscan2
- TONSL | c.1213G>A p.D405N | Missense Mutation (SNP) | VAF 47/785 reads (6%) | SIFT tolerated (0.33); PolyPhen possibly damaging (0.464); catalogued as rs933904130, COSV68048714; called by muse, mutect2
- BRK1 | c.184G>C p.E62Q | Missense Mutation (SNP) | VAF 19/405 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.663); called by muse, mutect2
- CACNA1H | c.4397A>G p.N1466S | Missense Mutation (SNP) | VAF 86/599 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); called by muse, mutect2, varscan2
- CEP135 | c.1580A>T p.K527I | Missense Mutation (SNP) | VAF 20/140 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- GBP4 | c.1412C>A p.A471E | Missense Mutation (SNP) | VAF 31/227 reads (14%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.8); called by muse, mutect2, varscan2
- IGLV8-61 | c.364_367delinsC p.I122del | In Frame Del (DEL) | VAF 47/286 reads (16%) | called by pindel, varscan2*
- PKD2L1 | c.1900G>T p.E634* | Nonsense Mutation (SNP) | VAF 48/356 reads (13%) | called by muse, mutect2, varscan2
- TBL1XR1 | c.1109A>T p.D370V | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); called by muse, mutect2
- TBL1XR1 | c.254dup p.D85Efs*6 | Frame Shift Ins (INS) | VAF 69/389 reads (18%) | called by mutect2, pindel, varscan2
- TTN | c.57923C>A p.P19308Q (on ENST00000591111; = p.P11884Q on NM_003319.4) | Missense Mutation (SNP) | VAF 65/506 reads (13%) | PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- UBA2 | c.1205G>A p.G402E | Missense Mutation (SNP) | VAF 38/303 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.374); called by muse, mutect2, varscan2
- ZDBF2 | c.5854A>T p.N1952Y | Missense Mutation (SNP) | VAF 48/373 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.598); called by muse, mutect2, varscan2
- APOA4 | c.480C>T p.Y160= | Silent (SNP) | VAF 132/778 reads (17%) | catalogued as rs538954345, COSV100759252, COSV63360358; called by muse, mutect2, varscan2
- CASS4 | c.1473A>G p.R491= | Silent (SNP) | VAF 64/414 reads (15%) | called by muse, mutect2, varscan2
- LCE1F | c.261C>A p.R87= | Silent (SNP) | VAF 44/654 reads (7%) | called by muse, mutect2
- OR51S1 | c.825C>A p.I275= | Silent (SNP) | VAF 18/474 reads (4%) | called by muse, mutect2
- PROKR2 | c.915C>T p.F305= | Silent (SNP) | VAF 63/392 reads (16%) | catalogued as rs1351399715, COSV54085406; called by muse, mutect2, varscan2
- FRMD4A | c.45+3198C>T | Intron (SNP) | VAF 67/467 reads (14%) | catalogued as rs935114031; called by muse, mutect2, varscan2
